Somatic mutation profile of tumor specimen HCM-SANG-0270-C20-86A (aliquot HCM-SANG-0270-C20-86A-01D-A85C-36) from HCMI case HCM-SANG-0270-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0270-C20-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69d29c03-4322-4c92-a7df-e701bae9a88d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0270-C20-10B (Blood Derived Normal), aliquot HCM-SANG-0270-C20-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55b49b05-46ca-41ec-b89d-131df6a6bd54

The open-access MAF lists 128 somatic variants for this specimen: 97 protein-altering or splice-affecting, 24 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 24, Intron 4, Frame Shift Del 3, Frame Shift Ins 2, 5'UTR 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 422/422 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 143/294 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 380/381 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ABHD12B | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 225/469 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1392372319; called by muse, mutect2, varscan2
- ACACA | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 241/456 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs145246486; called by muse, mutect2, varscan2
- ACACB | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 247/480 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs773666938, COSV58131696; called by muse, mutect2, varscan2
- ACADL | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs546101555; called by muse, mutect2, varscan2
- ADAM29 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 185/422 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV100822047; called by muse, mutect2, varscan2
- AHNAK2 | c.13366G>A p.V4456M | Missense Mutation (SNP) | VAF 259/547 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs569348872, COSV60926415; called by muse, mutect2, varscan2
- ANHX | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 117/305 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as rs1480651088, COSV101376525; called by muse, mutect2, varscan2
- APCDD1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 304/602 reads (50%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.479); catalogued as rs201834801; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 234/484 reads (48%) | catalogued as rs758608743; called by mutect2, varscan2
- ATG2A | c.5656G>A p.V1886M | Missense Mutation (SNP) | VAF 377/737 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765776372; called by muse, mutect2, varscan2
- AZI2 | c.1052T>C p.F351S | Missense Mutation (SNP) | VAF 195/368 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1354201699; called by muse, mutect2, varscan2
- BCL11A | c.1498G>A p.V500M (on ENST00000335712 / NM_001365609.1; = p.V534M on NM_018014.4) | Missense Mutation (SNP) | VAF 359/717 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs773235162, COSV100186570; called by muse, mutect2, varscan2
- BOP1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 751/1090 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1383645232; called by muse, mutect2, varscan2
- C2orf42 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 148/319 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1388504707; called by muse, mutect2, varscan2
- CBLN4 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 271/572 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV50353896; called by muse, mutect2, varscan2
- CEP164 | c.4174C>T p.R1392W | Missense Mutation (SNP) | VAF 110/216 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769676851, COSV99632450; called by muse, mutect2, varscan2
- CHD4 | c.2831G>A p.R944Q (on ENST00000357008 / NM_001363606.2; = p.R957Q on NM_001273.5) | Missense Mutation (SNP) | VAF 240/498 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs76359472, COSV104399234, COSV58904513; called by muse, mutect2, varscan2
- CHMP1A | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 197/370 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.335); catalogued as rs200323717; called by muse, mutect2, varscan2
- CMYA5 | c.8049A>C p.K2683N | Missense Mutation (SNP) | VAF 190/434 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV101484417; called by muse, mutect2, varscan2
- DACT2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 519/520 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748077283; called by muse, mutect2, varscan2
- F13B | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 159/361 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66376011; called by muse, mutect2, varscan2
- FST | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs1177495235; called by muse, mutect2, varscan2
- GABRD | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 327/675 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs749014692; called by muse, mutect2, varscan2
- GRIK1 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373016584; called by muse, mutect2, varscan2
- H2BC1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.931); catalogued as rs1351937593, COSV51236761; called by muse, mutect2, varscan2
- HEXIM2 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 257/523 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs1267872165; called by muse, mutect2, varscan2
- ILDR2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 201/416 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs937233990, COSV54833776; called by muse, mutect2, varscan2
- ITIH5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 256/258 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs759497987, COSV56909484; called by muse, mutect2, varscan2
- KIF23 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 122/252 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs756964640, COSV52980273; called by muse, mutect2, varscan2
- LRRC49 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 110/242 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs150271201; called by muse, mutect2, varscan2
- MAGI2 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 238/461 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1052002858, COSV62641530; called by muse, mutect2, varscan2
- MAST4 | c.7781C>T p.P2594L (on ENST00000403625 / NM_001164664.2; = p.P2405L on NM_015183.3) | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as rs745802491; called by muse, mutect2, varscan2
- MYBPC3 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 249/446 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs727503173; called by muse, mutect2, varscan2
- NLGN4X | c.2103C>A p.D701E | Missense Mutation (SNP) | VAF 206/422 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.751); catalogued as COSV99320586; called by muse, mutect2, varscan2
- NLRP4 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 187/414 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs772979970; called by muse, mutect2, varscan2
- NOTCH2 | c.5105G>A p.R1702Q | Missense Mutation (SNP) | VAF 161/360 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs999822357, COSV56709641; called by muse, mutect2, varscan2
- NRXN1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 160/330 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372823663; called by muse, mutect2, varscan2
- NTRK3 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 328/590 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs183806623, COSV100448367, COSV58112677, COSV58116202; called by muse, mutect2, varscan2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- OR4N2 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 247/1077 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs201108157, COSV60050074; called by muse, mutect2
- OR51E2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 191/422 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs142195646, COSV101211306; called by muse, mutect2, varscan2
- OR5J2 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 144/341 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV56623841; called by muse, mutect2, varscan2
- PKHD1L1 | c.7336C>T p.P2446S | Missense Mutation (SNP) | VAF 142/511 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs1343952887; called by muse, mutect2, varscan2
- PQBP1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 194/448 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs782506693; called by muse, mutect2, varscan2
- PRM1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 160/345 reads (46%) | PolyPhen probably damaging (0.928); catalogued as rs374230515; called by muse, mutect2, varscan2
- SERPINF1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs376520683; called by muse, mutect2, varscan2
- SIGLEC12 | c.1447G>A p.G483R (on ENST00000291707 / NM_053003.4; = p.G365R on NM_033329.2) | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as rs372236004; called by muse, mutect2, varscan2
- SNAPC2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 315/684 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs1009937630, COSV55604301; called by muse, mutect2, varscan2
- SRSF7 | c.381A>C p.R127S | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs148174608; called by muse, mutect2, varscan2
- TMEM225 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 238/489 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.578); catalogued as COSV66693732; called by muse, mutect2, varscan2
- TRPA1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 159/744 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.288); catalogued as COSV51555755; called by muse, mutect2, varscan2
- ADRA2C | c.1346A>C p.K449T | Missense Mutation (SNP) | VAF 180/376 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ANO4 | c.1078A>T p.M360L (on ENST00000392977 / NM_001286615.2; = p.M325L on NM_178826.4) | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CARTPT | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 187/396 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CTNNB1 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 288/290 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP1B1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 317/704 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DCLK1 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 156/499 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DNAH10 | c.11854G>A p.D3952N (on ENST00000409039; = p.D3891N on NM_207437.3) | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- EN2 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 202/400 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FAR2 | c.611_617del p.Y204Sfs*17 | Frame Shift Del (DEL) | VAF 160/381 reads (42%) | called by mutect2, pindel, varscan2
- FIZ1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 349/688 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GSDMC | c.570+1G>C p.X190_splice | Splice Site (SNP) | VAF 214/319 reads (67%) | called by muse, mutect2, varscan2
- HIBADH | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 310/628 reads (49%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.062); called by muse, mutect2
- HS3ST5 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 381/383 reads (99%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KIAA2012 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2
- LCORL | c.3869A>C p.N1290T | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAGEA11 | c.95_96+14del p.X32_splice | Splice Site (DEL) | VAF 114/295 reads (39%) | called by mutect2, pindel, varscan2
- NBPF15 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 224/878 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); called by muse, varscan2
- NFATC1 | c.1499A>C p.K500T | Missense Mutation (SNP) | VAF 316/655 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NFIB | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 160/343 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NHS | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 392/768 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR8K3 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 197/432 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- PAPLN | c.1925A>T p.H642L (on ENST00000554301; = p.H615L on NM_173462.4) | Missense Mutation (SNP) | VAF 323/709 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PCDH17 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 232/708 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PCDHB4 | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PCNX1 | c.1219T>G p.S407A | Missense Mutation (SNP) | VAF 213/469 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHLPP1 | c.4454A>G p.E1485G | Missense Mutation (SNP) | VAF 274/563 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3R1 | c.460_461del p.S154Lfs*12 | Frame Shift Del (DEL) | VAF 326/528 reads (62%) | called by pindel, varscan2
- PLEKHD1 | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 194/405 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKX | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 213/462 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN21 | c.2711T>G p.L904R | Missense Mutation (SNP) | VAF 180/374 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- REPS1 | c.2192T>G p.L731R (on ENST00000450536 / NM_001286611.2; = p.L730R on NM_031922.4) | Missense Mutation (SNP) | VAF 121/279 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RPL5 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 119/213 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- RPP25L | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 328/648 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- SEMA5B | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 358/759 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC15A3 | c.366_372del p.F123Tfs*63 | Frame Shift Del (DEL) | VAF 329/698 reads (47%) | called by mutect2, pindel, varscan2
- SYNE1 | c.5848G>T p.A1950S (on ENST00000367255 / NM_182961.4; = p.A1957S on NM_033071.3) | Missense Mutation (SNP) | VAF 214/436 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR4 | c.9059C>G p.A3020G | Missense Mutation (SNP) | VAF 167/342 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- VPS13C | c.9823G>C p.G3275R (on ENST00000644861 / NM_020821.3; = p.G3232R on NM_017684.5) | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS13C | c.2757A>C p.E919D (on ENST00000644861 / NM_020821.3; = p.E876D on NM_017684.5) | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ZBTB7B | c.1163A>C p.K388T (on ENST00000292176; = p.K422T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/305 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF564 | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 193/401 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF654 | c.1983_1984dup p.I662Tfs*6 | Frame Shift Ins (INS) | VAF 97/226 reads (43%) | called by mutect2, pindel, varscan2
- ZNF799 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 138/311 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCC4 | c.3883A>C p.R1295= | Silent (SNP) | VAF 152/418 reads (36%) | called by muse, mutect2, varscan2
- AGL | c.1656A>G p.V552= | Silent (SNP) | VAF 132/276 reads (48%) | called by muse, mutect2, varscan2
- ANKRD34C | c.756T>G p.S252= | Silent (SNP) | VAF 230/475 reads (48%) | catalogued as rs1232767770; called by muse, mutect2, varscan2
- AVPR1A | c.36G>A p.S12= | Silent (SNP) | VAF 231/449 reads (51%) | catalogued as rs1414515126, COSV54547254; called by muse, mutect2, varscan2
- CACNA1E | c.2433C>A p.L811= | Silent (SNP) | VAF 296/618 reads (48%) | called by muse, mutect2, varscan2
- CCSER1 | c.2316G>A p.A772= | Silent (SNP) | VAF 171/358 reads (48%) | catalogued as rs1397732187; called by muse, mutect2, varscan2
- CYP2C19 | c.306G>A p.L102= | Silent (SNP) | VAF 111/276 reads (40%) | catalogued as rs775372710; called by muse, mutect2, varscan2
- GJC2 | c.531G>A p.A177= | Silent (SNP) | VAF 316/668 reads (47%) | catalogued as rs776968941; called by muse, varscan2
- HERC1 | c.8082T>C p.L2694= | Silent (SNP) | VAF 152/305 reads (50%) | called by muse, mutect2, varscan2
- KIAA1549L | c.4641C>T p.I1547= (on ENST00000321505; = p.I1844= on NM_012194.3) | Silent (SNP) | VAF 216/432 reads (50%) | catalogued as rs368722488; called by muse, varscan2
- LRFN5 | c.1197T>G p.T399= | Silent (SNP) | VAF 159/331 reads (48%) | called by muse, mutect2, varscan2
- LSR | c.1845C>T p.Y615= (on ENST00000361790; = p.Y596= on NM_015925.6) | Silent (SNP) | VAF 290/591 reads (49%) | called by muse, mutect2, varscan2
- PASK | c.2403C>T p.T801= | Silent (SNP) | VAF 263/517 reads (51%) | catalogued as rs568061248, COSV52153621; called by muse, mutect2, varscan2
- SHANK3 | c.4077C>T p.S1359= | Silent (SNP) | VAF 267/581 reads (46%) | catalogued as rs754778424; called by muse, mutect2, varscan2
- SHCBP1L | c.384C>T p.D128= | Silent (SNP) | VAF 209/409 reads (51%) | catalogued as COSV100840934; called by muse, mutect2, varscan2
- SIPA1 | c.105G>A p.P35= | Silent (SNP) | VAF 375/797 reads (47%) | catalogued as rs768841771; called by muse, mutect2, varscan2
- SIT1 | c.435C>T p.P145= | Silent (SNP) | VAF 264/593 reads (45%) | catalogued as rs138376414, COSV52399632; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK2 | c.912G>A p.P304= | Silent (SNP) | VAF 256/541 reads (47%) | catalogued as rs377471915; called by muse, mutect2, varscan2
- SPIDR | c.669G>C p.L223= | Silent (SNP) | VAF 140/514 reads (27%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2208G>A p.E736= | Silent (SNP) | VAF 312/313 reads (100%) | called by muse, mutect2, varscan2
- TDRD9 | c.447C>T p.S149= | Silent (SNP) | VAF 129/237 reads (54%) | catalogued as COSV59142753; called by muse, mutect2, varscan2
- TGFBRAP1 | c.636C>T p.I212= | Silent (SNP) | VAF 215/413 reads (52%) | catalogued as rs772448911, COSV51515853; called by muse, mutect2, varscan2
- USP34 | c.7947G>A p.Q2649= | Silent (SNP) | VAF 156/340 reads (46%) | called by muse, mutect2, varscan2
- ZNF331 | c.1218C>A p.T406= | Silent (SNP) | VAF 163/345 reads (47%) | catalogued as rs764501728; called by muse, mutect2, varscan2
- AMPD2 | c.-66G>T | 5'UTR (SNP) | VAF 27/786 reads (3%) | called by muse, mutect2
- DEPDC5 | c.2120+126G>A | Intron (SNP) | VAF 151/293 reads (52%) | called by muse, mutect2, varscan2
- FBXL22 | c.354-562G>A | Intron (SNP) | VAF 245/558 reads (44%) | catalogued as rs1425407045; called by muse, mutect2, varscan2
- OSGIN1 | n.2012C>T | RNA (SNP) | VAF 302/626 reads (48%) | catalogued as rs536349060, COSV59423909; called by muse, mutect2, varscan2
- RBFOX1 | c.1071+415C>T | Intron (SNP) | VAF 198/422 reads (47%) | called by muse, mutect2, varscan2
- TFEC | c.-55A>T | 5'UTR (SNP) | VAF 210/442 reads (48%) | called by muse, mutect2, varscan2
- UNC13B | c.762-4654dup | Intron (INS) | VAF 183/409 reads (45%) | called by mutect2, pindel, varscan2
